Gene-level copy-number profile of specimen HCM-BROD-0227-C43-85M from HCMI case HCM-BROD-0227-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 40.5 years (14,805 days).
Specimen HCM-BROD-0227-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 738cfe24-a301-42dd-88a3-eabb4d5aa918.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0227-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/d1984144-5a06-48e6-acfc-b46bcbd0e9e2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 581; copy number 2: 17,677; copy number 3: 22,114; copy number 4: 12,655; copy number 5: 3,523; copy number 6: 1,433; copy number 7: 698; copy number 8: 185; copy number 9: 1; copy number 10: 31; copy number 11: 2; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr16:33,577,502–33,771,248, 4 genes (within-gene range 0–2): AC142384.1, BMS1P8, ENPP7P13, AC136428.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 918 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:82,892,390–83,065,841, 3 genes, copy number 7: UBE3D, LAP3P1, AL355613.1.
- chr17:40,219,304–40,565,472, 19 genes, copy number 7–8: WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1, CCR7.
- chr19:8,302,127–8,343,262, 5 genes, copy number 8 (within-gene range 3–8): CD320, AC010323.1, NDUFA7, RPS28, KANK3.
- chr19:8,374,373–8,502,640, 8 genes, copy number 8 (within-gene range 3–8): RAB11B-AS1, MIR4999, RAB11B, MARCHF2, AC136469.1, AC136469.2, HNRNPM, PRAM1.
- chr19:12,833,951–13,158,788, 31 genes, copy number 7 (within-gene range 3–7): MAST1, MIR6794, DNASE2, AC020934.2, KLF1, GCDH, RPS6P25, SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1, DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42.
- chr19:15,107,401–15,498,956, 21 genes, copy number 7: SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2.
- chr19:15,851,993–15,950,350, 8 genes, copy number 7: CLEC4O, CYP4F36P, CYP4F2, AC005336.2, AC005336.3, AC005336.1, CYP4F11, OR10H4.
- chr19:18,040,355–18,389,176, 23 genes, copy number 7: AC020904.1, RPS18P13, IL12RB1, MAST3, AC007192.2, AC007192.1, PIK3R2, IFI30, MPV17L2, RAB3A, AC005759.1, AC008397.2, PDE4C, AC008397.1, IQCN, JUND, MIR3188, RPL39P38, LSM4, RN7SL513P, PGPEP1, GDF15, MIR3189.
- chr19:19,385,826–19,529,054, 5 genes, copy number 8 (within-gene range 5–8): GATAD2A, AC092067.1, MIR640, TSSK6, NDUFA13.
- chr19:20,122,569–20,321,305, 1 gene, copy number 8 (within-gene range 4–8): AC011447.3.
- chr19:20,167,214–20,571,095, 19 genes, copy number 8 (within-gene range 3–8): ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1, BNIP3P18, AC078899.4, BNIP3P19, AC078899.5, ZNF826P, BNIP3P20, AC078899.2, MIR1270, BNIP3P22, AC008554.1, BNIP3P23.
- chr19:21,358,930–22,555,367, 55 genes, copy number 8: ZNF738, AC010615.3, AC010615.1, ZNF493, AC010615.4, AC010615.2, LINC00664, ZNF429, BNIP3P26, AC123912.1, AC123912.4, AC123912.2, AC123912.6, AC123912.5, AC123912.3, MTDHP3, MTDHP4, VN1R84P, ZNF100, CCNYL6, AC092364.1, BRI3BPP1, ZNF43, BNIP3P27, ZNF208, MTDHP2, AC003973.2, BNIP3P28, AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.1, AC073539.3, ZNF729, BNIP3P31, AC011494.1, RPL34P34, ZNF98, AC011516.1, BNIP3P32, AC025811.1, BNIP3P33, ZNF209P, AC004004.1, AC011467.6, AC011467.1, LINC01233, RNU6-1179P.
- chr19:34,092,561–34,127,423, 2 genes, copy number 7: RPS4XP21, CHCHD2P3.
- chr19:35,224,800–35,513,658, 23 genes, copy number 7: FAM187B, FAM187B2P, LSR, AC002128.2, AC002128.1, USF2, HAMP, MAG, CD22, U62631.1, MIR5196, FFAR1, FFAR3, GPR42, EEF1A1P7, LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2, KRTDAP, DMKN.
- chr19:42,387,019–45,305,284, 141 genes, copy number 7–13 (within-gene range 4–13) (broad region; genes not listed).
- chr19:52,453,553–54,155,681, 147 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr22:18,970,439–20,859,417, 101 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:22,547,701–22,580,296, 3 genes, copy number 7: PRAME, LL22NC03-63E9.3, IGLV2-34.
- chr22:24,719,034–24,927,578, 3 genes, copy number 8: PIWIL3, SGSM1, AL049759.1.
- chr22:25,199,858–26,780,893, 52 genes, copy number 8: CRYBB3, Z99916.1, CRYBB2, Z99916.3, AL022332.1, AL022324.4, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2, AL022329.1, GRK3, AL022329.2, YES1P1, RNA5SP494, MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3.
- chr22:27,978,014–28,679,865, 1 gene, copy number 8 (within-gene range 5–8): TTC28.
- chr22:28,303,754–29,191,808, 18 genes, copy number 8: Y_RNA, MIR5739, RN7SL162P, CHEK2, HSCB, CCDC117, XBP1, Z93930.2, Z93930.3, Z93930.1, ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P.
- chr22:30,447,959–30,932,449, 18 genes, copy number 7 (within-gene range 6–7): SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1, PES1, AC005006.1, TCN2, SLC35E4, DUSP18, AC003072.1, AC003072.2, OSBP2, MIR3200, EIF4HP2, MORC2-AS1.
- chr22:32,205,115–32,278,382, 2 genes, copy number 10 (within-gene range 6–10): SLC5A4-AS1, SLC5A4.
- chr22:33,104,330–33,145,861, 3 genes, copy number 7: LINC01640, Z82198.1, Z82198.3.
- chr22:36,703,918–39,492,194, 134 genes, copy number 7 (broad region; genes not listed).
- chr22:43,955,442–44,010,531, 1 gene, copy number 7 (within-gene range 2–7): SAMM50.
- chr22:43,999,211–45,601,135, 37 genes, copy number 7–10: PARVB, AL033543.1, AL031595.3, PARVG, AL031595.1, AL031595.2, SHISAL1, Z85994.1, Z85994.2, LINC01656, MRPS18CP6, AL023973.1, RTL6, KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8, PHF21B, Z83838.1, AL079301.1, NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1.
- chr22:45,671,798–46,762,563, 33 genes, copy number 7–10 (within-gene range 6–10): ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B, PPARA, FP325332.1, CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU, CELSR1, AL031597.1, AL021392.1, GRAMD4, CERK, AL118516.1.
- chr22:48,489,553–48,850,912, 1 gene, copy number 7 (within-gene range 2–7): TAFA5.

Autosomal genes at a single copy (total copy number 1): 72. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
